Somatic mutation profile of tumor specimen ALCH-B0HH-TTP1-A (aliquot ALCH-B0HH-TTP1-A-1-0-D-A714-36) from ALCHEMIST case ALCH-B0HH, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 71.0 years (25,938 days).
Specimen ALCH-B0HH-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a2f68320-3132-4782-a743-6462a684f6ff.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B0HH-NB1-A (Blood Derived Normal), aliquot ALCH-B0HH-NB1-A-1-0-D-A714-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/02510cca-a936-4e3e-9720-d05a2fa38a7f

The open-access MAF lists 171 somatic variants for this specimen: 117 protein-altering or splice-affecting, 30 silent, 24 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 96, Silent 30, Nonsense Mutation 11, Intron 8, Splice Site 5, 5'UTR 5, 3'UTR 4, RNA 4, Frame Shift Del 2, Splice Region 2, 5'Flank 2, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.581T>G p.L194R | Missense Mutation (SNP) | VAF 52/379 reads (14%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519998, COSV52663681, COSV52677924, COSV52679257, COSV52713187; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- AJAP1 | c.1054G>T p.E352* | Nonsense Mutation (SNP) | VAF 37/210 reads (18%) | catalogued as COSV65452111; called by muse, varscan2
- ARHGAP36 | c.1414C>A p.L472I | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.048); catalogued as COSV52270236; called by muse, mutect2, varscan2
- CALCR | c.487C>A p.L163I | Missense Mutation (SNP) | VAF 14/224 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1268412864, COSV64006016; called by muse, mutect2
- CDH12 | c.1594G>C p.A532P | Missense Mutation (SNP) | VAF 24/134 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.383); catalogued as COSV66389462; called by muse, varscan2
- COL22A1 | c.3647G>T p.G1216V | Missense Mutation (SNP) | VAF 30/267 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57323811; called by muse, mutect2, varscan2
- DNM3 | c.2173C>T p.R725W (on ENST00000355305 / NM_001350206.2; = p.R719W on NM_015569.5) | Missense Mutation (SNP) | VAF 35/322 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs765996640; called by muse, mutect2, varscan2
- DSG4 | c.502G>C p.E168Q | Missense Mutation (SNP) | VAF 16/274 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57390122; called by muse, mutect2
- FCRL3 | c.1480G>T p.E494* | Nonsense Mutation (SNP) | VAF 7/65 reads (11%) | catalogued as COSV63843752; called by muse, mutect2, varscan2
- FMN2 | c.2477G>T p.G826V | Missense Mutation (SNP) | VAF 16/133 reads (12%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.01); catalogued as COSV60427258; called by muse, mutect2, varscan2
- HOMER1 | c.235G>C p.D79H | Missense Mutation (SNP) | VAF 12/249 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56532118; called by muse, mutect2
- KCNT2 | c.2695C>G p.Q899E | Missense Mutation (SNP) | VAF 12/154 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV54063390; called by muse, mutect2
- KEAP1 | c.1672G>C p.G558R | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50355900; called by muse, mutect2, varscan2
- KLHL4 | c.1831G>A p.G611R | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as COSV64144840; called by muse, mutect2, varscan2
- LTN1 | c.265A>G p.T89A | Missense Mutation (SNP) | VAF 14/218 reads (6%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs893195235; called by muse, mutect2
- MON2 | c.520A>T p.T174S | Missense Mutation (SNP) | VAF 34/311 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.039); catalogued as rs766010591, COSV54808001; called by muse, mutect2, varscan2
- MYH2 | c.2329G>C p.G777R | Missense Mutation (SNP) | VAF 22/240 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV55436219; called by muse, mutect2
- NPIPA1 | c.772G>C p.D258H | Missense Mutation (SNP) | VAF 35/283 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.377); catalogued as rs753526176; called by muse, mutect2, varscan2
- OSBPL3 | c.1234del p.A412Lfs*21 | Frame Shift Del (DEL) | VAF 17/150 reads (11%) | catalogued as COSV57661547; called by mutect2, pindel, varscan2
- PCARE | c.1344G>C p.L448F | Missense Mutation (SNP) | VAF 10/133 reads (8%) | SIFT tolerated (0.71); PolyPhen benign (0.025); catalogued as COSV59052836; called by muse, mutect2
- POLD1 | c.2731G>T p.D911Y | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54529777, COSV54533183; called by muse, mutect2, varscan2
- RGSL1 | c.1442C>A p.P481H | Missense Mutation (SNP) | VAF 47/243 reads (19%) | SIFT tolerated (0.55); PolyPhen benign (0.006); catalogued as rs944963753; called by muse, mutect2, varscan2
- SERPINA11 | c.307C>A p.L103M | Missense Mutation (SNP) | VAF 20/180 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV58241526; called by muse, mutect2
- SLC35G5 | c.841C>G p.L281V | Missense Mutation (SNP) | VAF 18/141 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs772107882; called by muse, mutect2, varscan2
- SUSD3 | c.535C>T p.H179Y | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT tolerated (0.4); PolyPhen benign (0.021); catalogued as rs1478385644; called by muse, mutect2, varscan2
- SYT14 | c.1043A>G p.Y348C | Missense Mutation (SNP) | VAF 63/269 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1275065864; called by muse, mutect2, varscan2
- TTC14 | c.1145G>A p.C382Y | Missense Mutation (SNP) | VAF 14/189 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56013369; called by muse, mutect2
- ULK4 | c.907A>G p.M303V | Missense Mutation (SNP) | VAF 24/180 reads (13%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs766473119; called by muse, mutect2, varscan2
- USP40 | c.3392C>A p.P1131Q | Missense Mutation (SNP) | VAF 37/385 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.175); catalogued as COSV99295970; called by muse, mutect2, varscan2
- WNK2 | c.3367G>T p.A1123S | Missense Mutation (SNP) | VAF 22/200 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.824); catalogued as COSV52938504; called by muse, mutect2, varscan2
- ZNF248 | c.410A>G p.Y137C | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs1374963730; called by muse, mutect2, varscan2
- AARS2 | c.2027A>T p.Q676L | Missense Mutation (SNP) | VAF 25/133 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- AATF | c.1119G>C p.K373N | Missense Mutation (SNP) | VAF 22/154 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- ABCA3 | c.3142C>T p.H1048Y | Missense Mutation (SNP) | VAF 23/189 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- ABL2 | c.886G>T p.G296C (on ENST00000502732 / NM_007314.4; = p.G281C on NM_005158.5) | Missense Mutation (SNP) | VAF 12/290 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); called by muse, mutect2
- ACOT11 | c.367A>T p.M123L | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ACTN4 | c.605_607del p.I202_H203delinsN | In Frame Del (DEL) | VAF 43/425 reads (10%) | called by mutect2, pindel
- ADGRL2 | c.2881C>T p.P961S (on ENST00000370717 / NM_001366005.1; = p.P948S on NM_012302.4) | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- AP002748.5 | c.58G>T p.G20* | Nonsense Mutation (SNP) | VAF 16/183 reads (9%) | called by muse, mutect2
- ATXN10 | c.146G>T p.R49I | Missense Mutation (SNP) | VAF 14/298 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.061); called by muse, mutect2
- C10orf90 | c.2062-1G>T p.X688_splice | Splice Site (SNP) | VAF 12/75 reads (16%) | called by muse, mutect2, varscan2
- C12orf65 | c.408G>C p.K136N | Missense Mutation (SNP) | VAF 62/774 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.81); called by muse, mutect2
- C6orf118 | c.616C>G p.L206V | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CABIN1 | c.1036G>T p.A346S | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT tolerated (0.35); PolyPhen benign (0.001); called by muse, mutect2
- CACNA1I | c.4195-1G>A p.X1399_splice | Splice Site (SNP) | VAF 15/97 reads (15%) | called by muse, mutect2, varscan2
- CCNB3 | c.2017C>G p.Q673E | Missense Mutation (SNP) | VAF 17/103 reads (17%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.677); called by muse, mutect2, varscan2
- COG1 | c.866G>A p.G289D | Missense Mutation (SNP) | VAF 17/256 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.594); called by muse, mutect2
- DCAF8 | c.1264del p.A422Pfs*16 | Frame Shift Del (DEL) | VAF 36/239 reads (15%) | called by mutect2, pindel, varscan2
- DCDC1 | c.4885C>T p.H1629Y (on ENST00000597505 / NM_001367979.1; = p.H736Y on NM_020869.3) | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.09); called by muse, mutect2
- DNAJC1 | c.131C>G p.P44R | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); called by muse, varscan2
- ELP1 | c.1098G>T p.W366C | Missense Mutation (SNP) | VAF 24/252 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2
- EXT1 | c.601C>T p.P201S | Missense Mutation (SNP) | VAF 35/488 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- EYS | c.8821C>G p.L2941V (on ENST00000370621 / NM_001292009.1; = p.L2920V on NM_001142800.2) | Missense Mutation (SNP) | VAF 54/348 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- FAM135B | c.2173C>G p.R725G | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); called by mutect2, varscan2
- FAM186A | c.2607G>C p.Q869H | Missense Mutation (SNP) | VAF 16/418 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.06); called by muse, mutect2
- FBXW12 | c.576C>A p.C192* | Nonsense Mutation (SNP) | VAF 16/156 reads (10%) | called by muse, mutect2, varscan2
- GEN1 | c.307C>G p.Q103E | Missense Mutation (SNP) | VAF 8/141 reads (6%) | SIFT tolerated (0.81); PolyPhen benign (0.05); called by muse, mutect2
- HOXA6 | c.286C>G p.Q96E | Missense Mutation (SNP) | VAF 5/64 reads (8%) | SIFT tolerated (0.56); PolyPhen benign (0.05); called by muse, mutect2
- IRGC | c.1123G>T p.G375C | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- ITGA2B | c.96G>C p.L32F | Missense Mutation (SNP) | VAF 10/137 reads (7%) | SIFT tolerated (0.22); PolyPhen benign (0.056); called by muse, mutect2
- JAM3 | c.382G>C p.E128Q | Missense Mutation (SNP) | VAF 32/530 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- KDM5B | c.3832G>T p.V1278L | Missense Mutation (SNP) | VAF 18/150 reads (12%) | SIFT tolerated (0.65); PolyPhen benign (0); called by muse, mutect2, varscan2
- KDR | c.3941C>A p.T1314K | Missense Mutation (SNP) | VAF 25/300 reads (8%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.451); called by muse, mutect2
- LCP2 | c.1149A>T p.Q383H | Missense Mutation (SNP) | VAF 32/300 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.784); called by muse, mutect2
- LILRA5 | c.496C>A p.L166M | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.28); called by muse, mutect2, varscan2
- LILRB1 | c.565G>T p.G189C (on ENST00000427581; = p.G153C on NM_006669.6) | Missense Mutation (SNP) | VAF 24/260 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- LIMCH1 | c.785C>G p.S262* | Nonsense Mutation (SNP) | VAF 16/314 reads (5%) | called by muse, mutect2
- MAP4K1 | c.1449A>T p.G483= | Splice Region (SNP) | VAF 10/210 reads (5%) | called by muse, mutect2
- MROH8 | c.94C>G p.L32V | Missense Mutation (SNP) | VAF 21/173 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- MUC16 | c.16699A>T p.T5567S | Missense Mutation (SNP) | VAF 25/168 reads (15%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- NAA20 | c.452-1G>C p.X151_splice | Splice Site (SNP) | VAF 12/83 reads (14%) | called by muse, mutect2, varscan2
- NOTCH2 | c.3283G>T p.G1095C | Missense Mutation (SNP) | VAF 25/257 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NOVA1 | c.1014A>C p.Q338H | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.54); PolyPhen benign (0.367); called by mutect2, varscan2
- NPLOC4 | c.1210A>T p.K404* | Nonsense Mutation (SNP) | VAF 17/204 reads (8%) | called by muse, mutect2
- NPY1R | c.530A>T p.Q177L | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.167); called by muse, mutect2, varscan2
- OR10S1 | c.109T>A p.S37T | Missense Mutation (SNP) | VAF 21/294 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, mutect2
- OR2F1 | c.824C>T p.S275F | Missense Mutation (SNP) | VAF 11/209 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2
- OR51I2 | c.587G>T p.S196I | Missense Mutation (SNP) | VAF 13/170 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.015); called by muse, mutect2
- OR52B6 | c.775A>C p.T259P | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- OR8K5 | c.791C>G p.S264C | Missense Mutation (SNP) | VAF 15/132 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PACSIN1 | c.479A>G p.Y160C | Missense Mutation (SNP) | VAF 10/174 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2
- PASD1 | c.568G>T p.V190F | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT tolerated (0.37); PolyPhen benign (0.018); called by mutect2, varscan2
- PCARE | c.3337G>A p.A1113T | Missense Mutation (SNP) | VAF 23/616 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0.027); called by muse, mutect2
- PCARE | c.1396G>C p.E466Q | Missense Mutation (SNP) | VAF 20/181 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.231); called by muse, varscan2
- PFKM | c.1589C>A p.S530Y | Missense Mutation (SNP) | VAF 29/497 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- PLA1A | c.476C>A p.S159* | Nonsense Mutation (SNP) | VAF 15/198 reads (8%) | called by muse, mutect2
- PLCB4 | c.3036+2T>A p.X1012_splice | Splice Site (SNP) | VAF 29/235 reads (12%) | called by muse, mutect2, varscan2
- PLEKHG1 | c.2500G>A p.E834K | Missense Mutation (SNP) | VAF 21/284 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); called by muse, mutect2
- PLK4 | c.2737G>A p.D913N | Missense Mutation (SNP) | VAF 18/301 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RASGEF1B | c.911C>A p.S304Y | Missense Mutation (SNP) | VAF 15/186 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- RP1L1 | c.7013G>T p.R2338M | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.788); called by muse, mutect2, varscan2
- RTKN2 | c.513G>C p.Q171H | Missense Mutation (SNP) | VAF 12/114 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.823); called by muse, mutect2
- SCN7A | c.407C>A p.S136Y | Missense Mutation (SNP) | VAF 16/195 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); called by muse, mutect2
- SERPINA6 | c.305A>T p.E102V | Missense Mutation (SNP) | VAF 24/273 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); called by muse, mutect2
- SLC6A16 | c.1937G>C p.S646T | Missense Mutation (SNP) | VAF 20/189 reads (11%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- SLC8A1 | c.256G>A p.V86I | Missense Mutation (SNP) | VAF 16/216 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.024); called by muse, mutect2
- SLC9A3 | c.1869C>A p.Y623* | Nonsense Mutation (SNP) | VAF 8/62 reads (13%) | called by muse, mutect2, varscan2
- SMOC2 | c.1044G>T p.E348D (on ENST00000356284 / NM_001166412.2; = p.E359D on NM_022138.3) | Missense Mutation (SNP) | VAF 19/118 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.549); called by muse, mutect2
- SMOC2 | c.1045G>T p.E349* (on ENST00000356284 / NM_001166412.2; = p.E360* on NM_022138.3) | Nonsense Mutation (SNP) | VAF 19/123 reads (15%) | called by muse, mutect2
- SORBS1 | c.1511C>T p.S504F (on ENST00000361941 / NM_001034954.2; = p.S294F on NM_006434.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/150 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2
- SP140L | c.786G>C p.G262= | Splice Region (SNP) | VAF 10/223 reads (4%) | called by muse, mutect2
- SPATA21 | c.28A>T p.T10S | Missense Mutation (SNP) | VAF 10/162 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.039); called by muse, mutect2
- TCOF1 | c.1083+1G>T p.X361_splice (on ENST00000377797 / NM_001135243.1; = p.X284_splice on NM_000356.4) | Splice Site (SNP) | VAF 14/172 reads (8%) | called by muse, mutect2
- TCTE1 | c.449G>T p.S150I | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- TESPA1 | c.58C>T p.Q20* | Nonsense Mutation (SNP) | VAF 15/46 reads (33%) | called by muse, mutect2, varscan2
- TMC3 | c.1909T>A p.F637I | Missense Mutation (SNP) | VAF 27/286 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- TRPM2 | c.1624G>T p.E542* | Nonsense Mutation (SNP) | VAF 11/94 reads (12%) | called by muse, mutect2, varscan2
- TSR3 | c.728G>C p.R243T | Missense Mutation (SNP) | VAF 16/222 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.276); called by muse, mutect2
- ULBP2 | c.595A>T p.M199L | Missense Mutation (SNP) | VAF 10/154 reads (6%) | SIFT tolerated (0.28); PolyPhen benign (0.005); called by muse, mutect2
- URB1 | c.3755G>A p.C1252Y | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- VPS16 | c.583G>T p.V195L | Missense Mutation (SNP) | VAF 20/230 reads (9%) | SIFT tolerated (0.33); PolyPhen benign (0.014); called by muse, mutect2
- XKR3 | c.919C>A p.L307I | Missense Mutation (SNP) | VAF 12/155 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2
- YIPF7 | c.793T>G p.Y265D | Missense Mutation (SNP) | VAF 18/190 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- ZNF148 | c.2166A>C p.Q722H | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- ZNF341 | c.1699C>A p.P567T (on ENST00000375200 / NM_001282935.1; = p.P560T on NM_032819.4) | Missense Mutation (SNP) | VAF 40/227 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF709 | c.370C>T p.H124Y | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZNF805 | c.1840G>C p.D614H | Missense Mutation (SNP) | VAF 6/73 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.358); called by muse, mutect2
- ADAM28 | c.24C>T p.V8= | Silent (SNP) | VAF 12/232 reads (5%) | called by muse, mutect2
- CLCN1 | c.1425C>A p.T475= | Silent (SNP) | VAF 16/260 reads (6%) | called by muse, mutect2
- COL3A1 | c.1584C>G p.G528= | Silent (SNP) | VAF 10/142 reads (7%) | called by muse, mutect2
- DOCK5 | c.220C>T p.L74= | Silent (SNP) | VAF 26/320 reads (8%) | called by muse, mutect2
- ERCC2 | c.1005G>T p.R335= | Silent (SNP) | VAF 16/144 reads (11%) | called by muse, mutect2, varscan2
- FAM186A | c.2850G>A p.Q950= | Silent (SNP) | VAF 30/444 reads (7%) | catalogued as rs1418417686; called by muse, mutect2
- FANCM | c.3111G>A p.L1037= | Silent (SNP) | VAF 14/291 reads (5%) | catalogued as COSV57506855; called by muse, mutect2
- GAA | c.417G>A p.E139= | Silent (SNP) | VAF 18/262 reads (7%) | called by muse, mutect2
- HTD2 | c.423A>T p.A141= | Silent (SNP) | VAF 14/115 reads (12%) | called by muse, mutect2
- IGSF11 | c.1158C>A p.S386= (on ENST00000393775 / NM_001015887.3; = p.S385= on NM_152538.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 14/126 reads (11%) | catalogued as COSV100677742; called by muse, mutect2
- MYH15 | c.4623C>G p.V1541= | Silent (SNP) | VAF 16/240 reads (7%) | called by muse, mutect2
- OPN1LW | c.837C>A p.V279= | Silent (SNP) | VAF 23/108 reads (21%) | called by muse, mutect2, varscan2
- OR2T4 | c.897C>A p.T299= | Silent (SNP) | VAF 48/248 reads (19%) | called by muse, mutect2, varscan2
- OTULIN | c.759A>G p.V253= | Silent (SNP) | VAF 90/301 reads (30%) | called by muse, mutect2, varscan2
- PRKACB | c.489C>T p.L163= | Silent (SNP) | VAF 14/183 reads (8%) | called by muse, mutect2
- REM1 | c.96C>A p.R32= | Silent (SNP) | VAF 16/126 reads (13%) | called by muse, mutect2, varscan2
- RGSL1 | c.1443C>A p.P481= | Silent (SNP) | VAF 47/248 reads (19%) | called by muse, mutect2, varscan2
- RP1L1 | c.3108C>A p.P1036= | Silent (SNP) | VAF 10/70 reads (14%) | catalogued as COSV66753222; called by muse, mutect2, varscan2
- RTN1 | c.1884C>A p.A628= | Silent (SNP) | VAF 16/180 reads (9%) | called by muse, mutect2
- SLC8A1 | c.2706G>T p.V902= | Silent (SNP) | VAF 8/106 reads (8%) | called by muse, mutect2
- SPHKAP | c.2748T>C p.L916= | Silent (SNP) | VAF 30/257 reads (12%) | called by muse, mutect2, varscan2
- STOML3 | c.240G>T p.L80= | Silent (SNP) | VAF 30/214 reads (14%) | called by muse, mutect2, varscan2
- SYNE1 | c.23493G>A p.E7831= (on ENST00000367255 / NM_182961.4; = p.E7760= on NM_033071.3) | Silent (SNP) | VAF 16/307 reads (5%) | called by muse, mutect2
- TAAR8 | c.789A>G p.V263= | Silent (SNP) | VAF 12/94 reads (13%) | called by muse, varscan2
- TAS2R4 | c.264C>T p.F88= | Silent (SNP) | VAF 32/300 reads (11%) | catalogued as COSV56093618; called by muse, mutect2, varscan2
- TBX4 | c.804C>A p.P268= | Silent (SNP) | VAF 21/198 reads (11%) | called by muse, mutect2, varscan2
- TENM3 | c.2437C>A p.R813= | Silent (SNP) | VAF 19/160 reads (12%) | called by muse, mutect2, varscan2
- TRAF3IP3 | c.282A>T p.G94= | Silent (SNP) | VAF 8/54 reads (15%) | called by muse, mutect2, varscan2
- VTCN1 | c.654G>T p.T218= | Silent (SNP) | VAF 14/122 reads (11%) | catalogued as rs773797959, COSV60224885; called by muse, mutect2, varscan2
- ZBTB12 | c.1074C>T p.I358= | Silent (SNP) | VAF 10/92 reads (11%) | called by muse, mutect2, varscan2
- ABI3BP | c.1576+9241G>T | Intron (SNP) | VAF 19/180 reads (11%) | called by muse, mutect2, varscan2
- AKAP13 | c.662+113C>G | Intron (SNP) | VAF 10/130 reads (8%) | called by muse, mutect2
- BCAS3 | c.2075-4861G>A | Intron (SNP) | VAF 24/184 reads (13%) | called by muse, mutect2, varscan2
- CDH22 | c.-44C>T | 5'UTR (SNP) | VAF 4/27 reads (15%) | called by muse, mutect2, varscan2
- DZANK1 | c.1612-333G>A | Intron (SNP) | VAF 10/126 reads (8%) | called by muse, mutect2
- FARP2 | c.1893+1691C>G | Intron (SNP) | VAF 10/246 reads (4%) | called by muse, mutect2
- GCNT2 | chr6:10634085 T>C | 3'Flank (SNP) | VAF 6/82 reads (7%) | called by muse, mutect2
- GLIPR1L2 | chr12:75390350 G>A | 5'Flank (SNP) | VAF 14/339 reads (4%) | called by muse, mutect2
- HHLA2 | c.*14A>G | 3'UTR (SNP) | VAF 15/101 reads (15%) | called by muse, mutect2, varscan2
- MIR519B | n.15del | RNA (DEL) | VAF 24/254 reads (9%) | called by mutect2, pindel
- NUP210P1 | n.570C>A | RNA (SNP) | VAF 21/348 reads (6%) | called by muse, mutect2
- POU3F4 | c.-33C>A | 5'UTR (SNP) | VAF 20/93 reads (22%) | called by muse, mutect2, varscan2
- RFPL4AP1 | n.648C>A | RNA (SNP) | VAF 12/123 reads (10%) | called by muse, mutect2, varscan2
- RNA5-8SP2 | chr16:34158627 C>T | 5'Flank (SNP) | VAF 9/55 reads (16%) | catalogued as rs761580150; called by muse, mutect2, varscan2
- RNF17 | c.1240+826C>G | Intron (SNP) | VAF 23/162 reads (14%) | called by muse, mutect2, varscan2
- SERPINA3 | c.1068+17G>T | Intron (SNP) | VAF 24/278 reads (9%) | called by muse, mutect2
- SNORD115-26 | n.2G>T | RNA (SNP) | VAF 16/149 reads (11%) | called by muse, mutect2, varscan2
- TRHR | c.-10G>T | 5'UTR (SNP) | VAF 31/274 reads (11%) | called by muse, mutect2, varscan2
- TSNAXIP1 | c.-41A>T | 5'UTR (SNP) | VAF 29/263 reads (11%) | called by muse, mutect2, varscan2
- VAPA | c.418-17A>G | Intron (SNP) | VAF 20/154 reads (13%) | called by muse, mutect2, varscan2
- XIRP2 | c.*177G>T | 3'UTR (SNP) | VAF 15/189 reads (8%) | called by muse, mutect2
- XIRP2 | c.*779G>A | 3'UTR (SNP) | VAF 14/238 reads (6%) | called by muse, mutect2
- ZNF99 | c.*3217A>G | 3'UTR (SNP) | VAF 14/188 reads (7%) | called by muse, mutect2
- ZSCAN10 | c.-7G>T | 5'UTR (SNP) | VAF 3/22 reads (14%) | called by muse, mutect2
